TCGA case TCGA-A6-A566 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Colon; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/790266bc-c252-43f4-85d1-1b06ee529cf8

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 55 years; Vital status: Dead; Days to death: 758 days (2.1 years).

Diagnoses (2)
1. Mucinous adenocarcinoma (the primary disease): ICD-O-3 morphology code: 8480/3; ICD-10 code: C18.6; Tissue or organ of origin: Descending colon; Site of resection or biopsy: Descending colon; Classification of tumor: primary; Age at diagnosis: 55.3 years (20,181 days); Year of diagnosis: 2007; AJCC staging edition: 6th; AJCC pathologic T: T4; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 758 days (2.1 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 2; Lymph nodes tested: 13; Lymphatic invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 76 days; Days to treatment end: 253 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 76 days; Days to treatment end: 251 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Days to treatment start: 76 days; Days to treatment end: 251 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Days to treatment start: 76 days; Days to treatment end: 237 days; Treatment outcome: Progressive Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 56.0 years (20,438 days); Days to diagnosis: 257 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS.

Follow-up (2 entries)
- Day 257 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 257 days.
- Days to follow up: 758 days (2.1 years); Disease response: With Tumor.

Molecular and laboratory tests
- KRAS mutation, nos: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 66.1 kg; Height: 160 cm; BMI: 25.8.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A6-A566-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 380 mg.
  Slide TCGA-A6-A566-01A-01-TS1: Section location: Top; Percent tumor cells: 45; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 35; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 2.
- Sample TCGA-A6-A566-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A6-A566-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Colon Mucinous Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes; Lymphovascular invasion indicator: Yes; KRAS gene analysis indicator: Yes; KRAS mutation found: No; History colon polyps: No; Colon polyps at procurement indicator: No; New tumor event diagnosis indicator: Yes.
- New tumor event: New tumor event surgery: No; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; New tumor event diagnosis indicator: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 758 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 758 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 257 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-A6-A566-01A-11D-A28F-01): tumor purity 0.39, ploidy 2.1, whole-genome doublings 0.
